Gene-level copy-number profile of tumor specimen ALCH-B1N9-TTP1-A from ALCHEMIST case ALCH-B1N9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.9 years (22,966 days).
Specimen ALCH-B1N9-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f8552066-e9ed-4879-87bb-d2474f8dd80e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1N9-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/2ce359a2-8701-47b1-937a-e465893eea7f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 53; copy number 1: 2,352; copy number 2: 42,712; copy number 3: 8,836; copy number 4: 2,385; copy number 5: 1,611; copy number 6: 426; copy number 7: 7; copy number 10: 1; copy number 13: 1; copy number 15: 1; copy number 16: 1.

Homozygous deletions (total copy number 0; autosomes only): 53 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:43,021,623–43,036,500, 3 genes: RRP36, AL136304.1, RN7SL403P.
- chr7:129,756,266–129,785,185, 5 genes (within-gene range 0–1): RNA5SP244, MIR182, MIR96, MIR183, AC084864.1.
- chr7:131,661,952–131,662,624, 1 gene: EEF1B2P6.
- chr8:37,983,070–37,983,373, 1 gene: RPL12P48.
- chr9:133,079,900–133,087,355, 1 gene (within-gene range 0–2): CELP.
- chr10:47,749,758–47,763,592, 1 gene: FO681492.1.
- chr11:73,218,281–73,242,427, 1 gene (within-gene range 0–3): P2RY2.
- chr15:25,176,832–25,234,328, 32 genes (within-gene range 0–2): SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35.
- chr16:85,098,358–85,112,472, 1 gene: CIBAR2.
- chr17:16,439,505–16,441,298, 4 genes (within-gene range 0–2): SNORD49B, SNORD49A, AC093484.4, SNORD65.
- chr19:45,890,023–45,914,778, 2 genes: MYPOP, NANOS2.
- chr20:33,675,477–33,686,385, 1 gene: E2F1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,048 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:191,823,432–248,937,043, 1,173 genes, copy number 5 (broad region; genes not listed).
- chr7:37,032–27,024,907, 421 genes, copy number 5–6 (broad region; genes not listed).
- chr7:27,328,607–47,079,128, 362 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr7:158,856,558–159,233,377, 5 genes, copy number 5: DYNC2I1, LINC00689, VIPR2, AC007269.1, PIP5K1P2.
- chr14:18,343,038–18,343,144, 1 gene, copy number 7: RNU6-458P.
- chr16:48,081,006–48,620,148, 14 genes, copy number 5 (within-gene range 3–5): ABCC12, AC096996.2, ABCC11, LONP2, UBA52P8, AC023818.1, SIAH1, Metazoa_SRP, AC026470.3, AC026470.1, MOCS1P1, N4BP1, AC026470.2, RPS2P44.
- chr16:56,429,133–57,757,244, 68 genes, copy number 5 (broad region; genes not listed).
- chr16:90,173,217–90,222,851, 1 gene, copy number 10 (within-gene range 3–10): LINC02193.
- chr21:43,414,483–43,427,131, 1 gene, copy number 16: SIK1.
- chr21:43,461,960–43,479,534, 1 gene, copy number 15 (within-gene range 2–15): LINC00313.
- chr21:44,133,610–44,210,114, 1 gene, copy number 13 (within-gene range 2–13): GATD3A.

Autosomal genes at a single copy (total copy number 1): 2,352. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
